Somatic mutation profile of tumor specimen 0DXCUD from CCDI case PBCRJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.7 years (4,999 days).
Specimen 0DXCUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d57447d3-662d-47f6-b4bd-fffaf4c2ca30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXCU1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f4c511d-7632-4f76-83e5-8b26a9af0826

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 2, 3'UTR 1, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/432 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COX4I2 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200392726; called by muse, mutect2, varscan2
- NFE2L2 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs1416793394; called by muse, mutect2
- OCA2 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 126/467 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs768651740, COSV100667267, COSV62359262; called by muse, mutect2, varscan2
- OR4D9 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 25/424 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs370202918; called by muse, mutect2
- POLR3B | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57277875; called by muse, mutect2, varscan2
- BPIFB2 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.028); called by muse, mutect2
- GPR37L1 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- LINGO1 | c.1657_1659del p.D553del | In Frame Del (DEL) | VAF 118/379 reads (31%) | called by mutect2, pindel, varscan2
- MLKL | c.1241-1G>T p.X414_splice | Splice Site (SNP) | VAF 36/352 reads (10%) | called by muse, mutect2
- NOL8 | c.1898C>G p.A633G | Missense Mutation (SNP) | VAF 69/567 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VWF | c.2275C>A p.H759N | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CR1L | c.1572C>T p.R524= | Silent (SNP) | VAF 155/567 reads (27%) | called by muse, mutect2, varscan2
- IRF3 | c.489C>T p.A163= | Silent (SNP) | VAF 122/463 reads (26%) | catalogued as rs368729955; called by muse, mutect2, varscan2
- OBSCN | c.8088C>T p.H2696= | Silent (SNP) | VAF 27/277 reads (10%) | catalogued as rs538378123; called by muse, mutect2
- RGS3 | c.1230C>T p.C410= (on ENST00000350696 / NM_001282923.2; = p.C298= on NM_017790.4) | Silent (SNP) | VAF 52/361 reads (14%) | catalogued as rs1379214177; called by muse, mutect2, varscan2
- TOGARAM1 | c.2535T>G p.V845= | Silent (SNP) | VAF 16/456 reads (4%) | called by muse, mutect2
- C15orf54 | n.427C>T | RNA (SNP) | VAF 56/548 reads (10%) | catalogued as rs770581044; called by muse, mutect2
- CHD7 | c.3378+45T>C | Intron (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- HDAC9 | c.*3077dup | 3'UTR (INS) | VAF 10/70 reads (14%) | called by mutect2, pindel
- SPTAN1 | c.3544-82C>T | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
